Somatic mutation profile of tumor specimen MMRF_2577_1_BM_CD138pos (aliquot MMRF_2577_1_BM_CD138pos_T1_KHS5U_K15139) from MMRF case MMRF_2577, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 51.3 years (18,753 days).
Specimen MMRF_2577_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d5f8b5e7-b264-43ff-98a9-3638df4c1f34.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2577_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2577_1_PB_Whole_C2_KHS5U_K15138; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b6caf9a1-b04c-4943-acb4-2960b22edd32

The open-access MAF lists 69 somatic variants for this specimen: 30 protein-altering or splice-affecting, 11 silent, 28 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, 3'UTR 15, Silent 11, Intron 8, Frame Shift Del 5, RNA 2, Splice Region 2, 5'UTR 1, 3'Flank 1, Nonsense Mutation 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 20/50 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAM2 | c.1355G>T p.C452F | Missense Mutation (SNP) | VAF 66/127 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55869777; called by muse, mutect2, varscan2
- AMHR2 | c.1037C>T p.S346L | Missense Mutation (SNP) | VAF 50/102 reads (49%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.951); catalogued as rs368193312; called by muse, mutect2, varscan2
- CDKN1B | c.407del p.D136Vfs*9 | Frame Shift Del (DEL) | VAF 27/84 reads (32%) | catalogued as COSV57429693; called by mutect2, pindel, varscan2
- DNAH8 | c.5867G>A p.R1956H | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs139579198, COSV59427962; called by muse, mutect2, varscan2
- ELN | c.164C>T p.A55V | Missense Mutation (SNP) | VAF 61/110 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs1411248717, CM060252; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FAM83A | c.662G>A p.R221Q | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs562444243; called by muse, mutect2
- MGAT4C | c.1174del p.I392Lfs*3 | Frame Shift Del (DEL) | VAF 36/74 reads (49%) | catalogued as rs746398787; called by mutect2, varscan2
- PBXIP1 | c.1832G>A p.R611Q | Missense Mutation (SNP) | VAF 70/204 reads (34%) | SIFT tolerated (0.61); PolyPhen benign (0.071); catalogued as rs549659614; called by muse, mutect2, varscan2
- RAB12 | c.673C>A p.Q225K | Missense Mutation (SNP) | VAF 16/138 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.93); catalogued as rs1027819367; called by muse, mutect2, varscan2
- RCL1 | c.708G>A p.G236= | Splice Region (SNP) | VAF 23/89 reads (26%) | catalogued as rs776940149; called by muse, mutect2, varscan2
- ABL1 | c.552C>G p.L184= | Splice Region (SNP) | VAF 24/148 reads (16%) | called by mutect2, varscan2
- AMOT | c.1022del p.N341Tfs*34 | Frame Shift Del (DEL) | VAF 70/98 reads (71%) | called by mutect2, pindel, varscan2
- BHLHE41 | c.764G>T p.G255V | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT tolerated (0.34); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DYNC1LI1 | c.953A>G p.K318R | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- ERBIN | c.2803G>C p.D935H | Missense Mutation (SNP) | VAF 5/127 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.75); called by muse, mutect2
- HSDL2 | c.478G>A p.V160I | Missense Mutation (SNP) | VAF 36/144 reads (25%) | SIFT tolerated (0.64); PolyPhen benign (0); called by muse, mutect2, varscan2
- IFTAP | c.415T>G p.C139G | Missense Mutation (SNP) | VAF 22/137 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- IGHV2-70D | c.154_157delinsAT p.G52Ifs*21 | Frame Shift Del (DEL) | VAF 37/39 reads (95%) | called by pindel, varscan2*
- KIAA1549 | c.2731G>T p.E911* | Nonsense Mutation (SNP) | VAF 7/139 reads (5%) | called by muse, mutect2
- METAP1 | c.211G>A p.G71S | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PCDHB14 | c.103G>A p.V35M | Missense Mutation (SNP) | VAF 67/204 reads (33%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.383); called by muse, mutect2, varscan2
- RTN2 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 76/217 reads (35%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SEMA6B | c.1454G>C p.R485T | Missense Mutation (SNP) | VAF 42/314 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- SHLD1 | c.581A>C p.H194P | Missense Mutation (SNP) | VAF 86/172 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.176); called by muse, mutect2, varscan2
- SNX17 | c.40G>C p.D14H | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.482); called by muse, mutect2, varscan2
- TENT5C | c.273_283del p.D92Pfs*14 | Frame Shift Del (DEL) | VAF 7/74 reads (9%) | called by mutect2, pindel
- USP39 | c.1553T>A p.V518E | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- WDR75 | c.2113C>G p.Q705E | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ZNF727 | c.457G>A p.A153T | Missense Mutation (SNP) | VAF 16/205 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.059); called by muse, mutect2
- ABCA13 | c.195T>C p.C65= | Silent (SNP) | VAF 44/100 reads (44%) | catalogued as COSV70026864; called by muse, mutect2, varscan2
- APLP1 | c.993A>G p.E331= | Silent (SNP) | VAF 70/210 reads (33%) | catalogued as rs1464905605; called by muse, mutect2, varscan2
- AQP3 | c.741C>T p.I247= | Silent (SNP) | VAF 31/184 reads (17%) | catalogued as rs768600882; called by muse, mutect2, varscan2
- ASB18 | c.405C>T p.C135= | Silent (SNP) | VAF 11/21 reads (52%) | called by muse, mutect2, varscan2
- CD300LG | c.267G>A p.S89= | Silent (SNP) | VAF 52/125 reads (42%) | catalogued as rs1049713176, COSV53224046; called by muse, mutect2, varscan2
- CNTN2 | c.1296C>T p.R432= | Silent (SNP) | VAF 65/147 reads (44%) | catalogued as rs781749087, COSV59352289; called by muse, mutect2, varscan2
- IGLV3-1 | c.207T>C p.D69= | Silent (SNP) | VAF 67/133 reads (50%) | catalogued as rs376313046; called by muse, mutect2, varscan2
- KLRG2 | c.1122C>T p.D374= | Silent (SNP) | VAF 53/111 reads (48%) | catalogued as rs761633991, COSV61800962; called by muse, mutect2, varscan2
- OR8S1 | c.1062G>A p.A354= | Silent (SNP) | VAF 35/82 reads (43%) | catalogued as rs1480531577, COSV59600243; called by muse, mutect2, varscan2
- SLC9A1 | c.1197C>T p.G399= | Silent (SNP) | VAF 53/74 reads (72%) | catalogued as rs138422424; called by muse, mutect2, varscan2
- XPA | c.12C>T p.A4= | Silent (SNP) | VAF 25/71 reads (35%) | catalogued as rs377130468; called by muse, mutect2, varscan2
- ACSL6 | chr5:131952950 ins A | 3'Flank (INS) | VAF 44/127 reads (35%) | catalogued as rs978324223; called by mutect2, varscan2
- CACNA1E | c.*7458G>C | 3'UTR (SNP) | VAF 58/105 reads (55%) | called by muse, mutect2, varscan2
- CCDC141 | c.1899+2312C>T | Intron (SNP) | VAF 24/54 reads (44%) | called by muse, mutect2, varscan2
- DOCK4 | c.*74G>A | 3'UTR (SNP) | VAF 58/127 reads (46%) | catalogued as rs1018094534, COSV101447798; called by muse, mutect2, varscan2
- DRP2 | c.*2885A>T | 3'UTR (SNP) | VAF 16/36 reads (44%) | called by muse, mutect2, varscan2
- FAM53C | c.*13A>G | 3'UTR (SNP) | VAF 7/50 reads (14%) | catalogued as rs1478894868; called by muse, mutect2, varscan2
- FARP1 | c.*4317C>T | 3'UTR (SNP) | VAF 36/76 reads (47%) | catalogued as rs1371745011; called by muse, mutect2, varscan2
- HIPK2 | c.*3005T>A | 3'UTR (SNP) | VAF 7/33 reads (21%) | called by muse, mutect2, varscan2
- HYDIN2 | n.5755G>A | RNA (SNP) | VAF 29/61 reads (48%) | called by muse, mutect2, varscan2
- LNPEP | c.*2166T>G | 3'UTR (SNP) | VAF 19/36 reads (53%) | called by muse, mutect2, varscan2
- MARCHF11 | c.*162_*163del | 3'UTR (DEL) | VAF 16/70 reads (23%) | called by mutect2, pindel, varscan2
- MASP1 | c.5+96G>A | Intron (SNP) | VAF 165/232 reads (71%) | catalogued as rs1385035409; called by muse, mutect2, varscan2
- MITF | c.*109T>A | 3'UTR (SNP) | VAF 98/141 reads (70%) | called by muse, mutect2, varscan2
- NLGN1 | c.*1584T>A | 3'UTR (SNP) | VAF 13/112 reads (12%) | called by muse, mutect2, varscan2
- PHC1P1 | n.2010C>T | RNA (SNP) | VAF 91/190 reads (48%) | called by muse, mutect2, varscan2
- PIAS2 | chr18:46920128 A>T | 5'Flank (SNP) | VAF 49/102 reads (48%) | called by muse, mutect2, varscan2
- PITX2 | c.390+450G>A | Intron (SNP) | VAF 7/15 reads (47%) | called by muse, mutect2, varscan2
- PMP22 | c.*521G>A | 3'UTR (SNP) | VAF 36/88 reads (41%) | catalogued as rs1454843933, COSV100396783; called by muse, mutect2, varscan2
- PPP2R5C | c.1443+3300A>C | Intron (SNP) | VAF 9/19 reads (47%) | called by mutect2, varscan2
- S100B | c.-1-194G>A | Intron (SNP) | VAF 13/73 reads (18%) | called by muse, mutect2, varscan2
- SEC61A1 | c.*1195C>T | 3'UTR (SNP) | VAF 34/98 reads (35%) | catalogued as rs984285939; called by muse, mutect2
- SLC4A4 | c.1903+251C>T | Intron (SNP) | VAF 22/53 reads (42%) | called by muse, mutect2, varscan2
- SLC5A9 | c.*293C>T | 3'UTR (SNP) | VAF 7/152 reads (5%) | called by muse, mutect2
- TMED7-TICAM2 | c.*775T>C | 3'UTR (SNP) | VAF 26/83 reads (31%) | catalogued as rs373462258; called by muse, mutect2, varscan2
- TMEM262 | c.174+20G>A | Intron (SNP) | VAF 45/149 reads (30%) | catalogued as rs991555358; called by muse, mutect2, varscan2
- TMEM266 | c.653-64C>T | Intron (SNP) | VAF 34/42 reads (81%) | catalogued as rs550749507; called by mutect2, varscan2
- UGT3A1 | c.-33A>T | 5'UTR (SNP) | VAF 83/274 reads (30%) | called by muse, mutect2, varscan2
- ZFP3 | c.*9A>G | 3'UTR (SNP) | VAF 34/68 reads (50%) | called by muse, mutect2, varscan2
